Somatic mutation profile of tumor specimen MP2PRT-PAVUHD-TMP1-A (aliquot MP2PRT-PAVUHD-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVUHD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,540 days).
Specimen MP2PRT-PAVUHD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 901c4305-461a-46f8-9dc0-ccabd5aa9266.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUHD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUHD-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afbed92b-fe5d-466a-9f56-48c66aee7f1f

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 8, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 223/560 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs397507544, CM044932, COSV61005111; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ENOSF1 | c.506C>T p.A169V (on ENST00000340116 / NM_001354066.2; = p.A121V on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 246/538 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs763758268, COSV51891382, COSV99201147; called by muse, mutect2, varscan2
- NXF3 | c.1132A>G p.I378V | Missense Mutation (SNP) | VAF 212/489 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs1338627266; called by muse, mutect2, varscan2
- SPDYE3 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); catalogued as rs1218106114; called by mutect2, varscan2
- DPYSL5 | c.1066A>G p.S356G | Missense Mutation (SNP) | VAF 163/416 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NR2F2 | c.470C>A p.T157N | Missense Mutation (SNP) | VAF 286/773 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAX5 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 319/797 reads (40%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 213/622 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PTPRQ | c.5434A>G p.T1812A (on ENST00000616559; = p.T1770A on NM_001145026.2) | Missense Mutation (SNP) | VAF 218/558 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- GBA2 | c.2088G>A p.V696= | Silent (SNP) | VAF 224/602 reads (37%) | catalogued as rs749376850, COSV62306470; called by muse, mutect2, varscan2
- GRIPAP1 | c.945T>C p.D315= | Silent (SNP) | VAF 193/498 reads (39%) | called by muse, mutect2, varscan2
- IGF1R | c.732C>T p.N244= | Silent (SNP) | VAF 310/802 reads (39%) | catalogued as rs765728831, COSV51279394, COSV51316187; called by muse, mutect2, varscan2
- PAX5 | c.666G>A p.K222= | Silent (SNP) | VAF 316/791 reads (40%) | called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.447G>C p.L149= | Silent (SNP) | VAF 176/470 reads (37%) | called by muse, mutect2, varscan2
- RGMA | c.9G>A p.P3= | Silent (SNP) | VAF 23/759 reads (3%) | called by muse, mutect2
